Surgical pathology report (de-identified scan), TCGA case TCGA-06-6700, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6700-01A (Primary Tumor).

[page 1 of 3]
TCGA-06-6700

Surgical Pathology Report

CLINICAL HISTORY

experienced secondary
probably to a
stroke, and has past history of prostate carcinoma. On imaging there
is a 3 x
5 cm, ring enhancing lesion in the posterior right temporal lobe.

OPERATIVE DIAGNOSES
Brain mass

Operation/Specimen: A: Brain tumor, right temporal, biopsy
B: Brain tumor, right temporal, biopsy

PATHOLOGICAL DIAGNOSIS:
A and B. Brain, right temporal, excisional biopsies:
1. Glioblastoma.
2. MIB-1 proliferation index: 35%.
See Microscopy Description and Comment.

COMMENT

The specimens are portions of cerebrum that are focally infiltrated
and
extensively effaced by an astrocytic neoplastic proliferation that has
nuclear
anaplasia, mitotic figures, microvascular cellular proliferation and
necrosis,
and extensive zones of tumor necrosis. The MIB1 proliferation
activity is
high at about 30%. There is not epithelial neoplasm.

The neoplasm is a glioblastoma (WH IV).

[page 2 of 3]
PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION:

Testing performed on RNA extracted from paraffin block

H slide was examined and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is amplified, overexpressed, and/or mutated in up

to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

[page 3 of 3]
the context of established procedures and/or diagnostic criteria.

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Source: NCI Genomic Data Commons file b476aa61-c399-484c-a10b-ef118b9b3298 (TCGA-06-6700.7217DC7F-5DF1-4B92-A7A7-6BF85DC8856E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).